Somatic mutation profile of tumor specimen HCM-SANG-0284-C18-01A (aliquot HCM-SANG-0284-C18-01A-01D-A78M-36) from HCMI case HCM-SANG-0284-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0284-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 563a524b-c7b7-4201-9d7d-a662913bbe64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0284-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0284-C18-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac92d1ee-8c6e-4570-9fed-ff1266c35b69

The open-access MAF lists 85 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 16, Intron 4, RNA 2, 5'UTR 2, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABRA | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 54/445 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs750305260; called by muse, mutect2, varscan2
- ADCY8 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53909347; called by muse, mutect2
- CCDC168 | c.18224G>A p.R6075H | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs780108376, COSV100487700; called by muse, mutect2, varscan2
- CNKSR2 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs759498814, COSV54249894; ClinVar: benign; called by muse, mutect2, varscan2
- CRAT | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1409754786; called by muse, mutect2
- DDX55 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs1481946540, COSV104379737; called by muse, mutect2, varscan2
- DNAH7 | c.10996G>A p.E3666K | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs761386813, COSV56766886; called by muse, mutect2, varscan2
- GBA2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs954541417; called by muse, mutect2
- ITIH4 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.887); catalogued as rs1559480944; called by muse, mutect2
- KLHL18 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs773078483, COSV51746366; called by muse, mutect2
- LATS2 | c.2888G>A p.G963E | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66878660; called by muse, mutect2
- LRRC8E | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1300239043; called by muse, mutect2, varscan2
- MYO1G | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs763720788, COSV51853574; called by muse, mutect2
- OBSCN | c.14665C>T p.R4889W | Missense Mutation (SNP) | VAF 69/627 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746013384; called by muse, mutect2, varscan2
- PIANP | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as rs1381414649; called by muse, mutect2, varscan2
- PNPLA6 | c.1032C>T p.H344= (on ENST00000414982 / NM_001166111.2; = p.H296= on NM_006702.5) | Splice Region (SNP) | VAF 38/297 reads (13%) | catalogued as rs769241929; called by muse, mutect2, varscan2
- PTH1R | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 25/421 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775797881, COSV57317330; called by muse, mutect2
- RBPJL | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1393715236; called by muse, mutect2
- RPRD2 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as rs201375427; called by muse, mutect2, varscan2
- SLC52A2 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs371806077; ClinVar: uncertain significance; called by muse, mutect2
- SPATS1 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895918148, COSV55822633, COSV55823090; called by muse, mutect2, varscan2
- ST6GAL2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 16/123 reads (13%) | PolyPhen benign (0.017); catalogued as rs775329379; called by muse, mutect2, varscan2
- TBC1D13 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 59/419 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs759494731; called by muse, mutect2, varscan2
- TET3 | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1188197678, COSV104434475; called by muse, mutect2
- TFAP2A | c.862G>A p.V288I (on ENST00000482890; = p.V280I on NM_001032280.3) | Missense Mutation (SNP) | VAF 27/366 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs755697313; called by muse, mutect2
- TLR8 | c.673C>T p.R225C (on ENST00000218032 / NM_138636.5; = p.R243C on NM_016610.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs757616604; called by muse, mutect2, varscan2
- TP53 | c.761dup p.I255Hfs*9 | Frame Shift Ins (INS) | VAF 54/265 reads (20%) | catalogued as COSV104370837; called by mutect2, pindel, varscan2
- TRIM51GP | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as rs571910105; called by muse, mutect2, varscan2
- TRPC4 | c.2666G>T p.R889L (on ENST00000379705 / NM_016179.4; = p.R894L on NM_003306.3) | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as rs761582713, COSV100157457, COSV58994204; called by muse, mutect2
- UBASH3B | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 35/532 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs764362576, COSV99418248; called by muse, mutect2
- VWCE | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs747777007, COSV100076032, COSV57112874; called by muse, mutect2
- VWF | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746810319, CM1111383, COSV54610419; ClinVar: uncertain significance; called by muse, mutect2
- ADAM22 | c.1324C>A p.L442I | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ADM5 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2
- AK5 | c.268T>A p.F90I (on ENST00000354567 / NM_174858.3; = p.F64I on NM_012093.4) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.182); called by muse, mutect2
- ALDH18A1 | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- BMS1 | c.2338T>C p.Y780H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BTK | c.1495C>A p.L499I | Missense Mutation (SNP) | VAF 63/590 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C8orf48 | c.258A>C p.K86N | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2
- CACNA1F | c.5354T>C p.L1785P | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- CCNP | c.548_550del p.F183del | In Frame Del (DEL) | VAF 18/155 reads (12%) | called by mutect2, pindel, varscan2
- CGN | c.2563A>G p.N855D | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2
- DNHD1 | c.8536G>C p.E2846Q | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- FAM120B | c.2439G>C p.K813N | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); called by muse, mutect2
- GTF3C2 | c.2380C>T p.H794Y | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- KIAA2026 | c.1835T>A p.F612Y | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.187); called by muse, mutect2
- LPAR4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.913); called by muse, mutect2
- MYO3A | c.840A>C p.E280D | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NEK8 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 42/610 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLGN4X | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 17/451 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- OOSP1 | c.225C>G p.F75L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, mutect2
- OVCH1 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.201); called by muse, mutect2
- PEBP1 | c.173T>A p.L58H | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.587); called by muse, mutect2
- PSG6 | c.237T>G p.I79M | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- WDR90 | c.3874G>T p.E1292* | Nonsense Mutation (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2, varscan2
- XIRP1 | c.5504G>T p.C1835F | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); called by muse, mutect2
- ZNF837 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ABCA13 | c.13069T>C p.L4357= | Silent (SNP) | VAF 16/372 reads (4%) | catalogued as COSV101291390; called by muse, mutect2
- B3GNT5 | c.315C>T p.S105= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs750868890; called by muse, mutect2, varscan2
- C2orf78 | c.2013C>T p.L671= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as COSV68517497; called by muse, mutect2, varscan2
- C3 | c.1557G>A p.L519= | Silent (SNP) | VAF 48/323 reads (15%) | called by muse, mutect2, varscan2
- CEP170B | c.4335G>A p.S1445= (on ENST00000453495; = p.S1374= on NM_015005.3) | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as rs780628198; called by muse, mutect2, varscan2
- CMKLR1 | c.159C>T p.L53= (on ENST00000312143 / NM_001142344.2; = p.L51= on NM_004072.3) | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as rs757850821; called by muse, mutect2
- CSMD1 | c.9309G>T p.P3103= (on ENST00000520002; = p.P3102= on NM_033225.6) | Silent (SNP) | VAF 27/175 reads (15%) | catalogued as COSV59315534; called by muse, mutect2, varscan2
- GAS2 | c.645C>T p.C215= | Silent (SNP) | VAF 17/247 reads (7%) | called by muse, mutect2
- KIF9 | c.1068C>G p.V356= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as rs1054875746, COSV55519430; called by muse, mutect2
- MUCL3 | c.1212T>C p.S404= (on ENST00000304311; = p.S1280= on NM_080870.4) | Silent (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- NOS3 | c.2466G>A p.A822= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs558767937; called by muse, mutect2, varscan2
- PSMD1 | c.9C>G p.T3= | Silent (SNP) | VAF 30/198 reads (15%) | called by muse, mutect2, varscan2
- SCN9A | c.4974C>T p.Y1658= (on ENST00000303354; = p.Y1647= on NM_002977.3) | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as rs757858235, COSV57600994; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHISA7 | c.1254C>T p.P418= | Silent (SNP) | VAF 38/275 reads (14%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1218G>A p.S406= (on ENST00000517878 / NM_001286646.2; = p.S355= on NM_001080431.2) | Silent (SNP) | VAF 25/308 reads (8%) | catalogued as rs771261958, COSV99200974; called by muse, mutect2
- SPINK5 | c.1509G>A p.V503= | Silent (SNP) | VAF 22/365 reads (6%) | called by muse, mutect2
- KL | c.1599+43T>C | Intron (SNP) | VAF 42/293 reads (14%) | called by muse, mutect2, varscan2
- MRRFP1 | n.676C>G | RNA (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
- MTRR | c.56+47G>A | Intron (SNP) | VAF 28/452 reads (6%) | called by muse, mutect2
- NACA | c.71-4387C>A | Intron (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- NMT2 | c.111-13426G>T | Intron (SNP) | VAF 44/373 reads (12%) | called by muse, mutect2, varscan2
- PPP1R3C | c.-16G>A | 5'UTR (SNP) | VAF 67/455 reads (15%) | catalogued as rs773657244; called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25087852 T>C | 3'Flank (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- TMEM235 | c.-495G>A | 5'UTR (SNP) | VAF 16/328 reads (5%) | catalogued as rs1346048509; called by muse, mutect2
- TP73-AS1 | n.1277C>T | RNA (SNP) | VAF 38/354 reads (11%) | catalogued as rs755690165; called by muse, mutect2, varscan2
- XIAP | c.*58G>A | 3'UTR (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
